Surgical pathology report (de-identified scan), TCGA case TCGA-29-1704, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1704-01B (Primary Tumor).

[page 1 of 3]
Surg Path

CLINICAL HISTORY:

Malignant neoplasm ovary.

GROSS EXAMINATION:

A. "Left ovary and tube", received fresh. The specimen consists of a 10 x 6.5 x 4 cm pink-tan mass which weighs 98.9 grams and has a length of 7.5 cm fallopian tube which measures 1.2 cm in diameter associated with it. The specimen has a cystic structure associated with it which measures 2.5 cm. The cystic area is sectioned to reveal a brown serous fluid. The surface of the specimen varies from pink-tan and has glistening areas of excrescence and granulation. A 1.2 cm diameter area on the surface appears to be disrupted. The inside rim of the cyst appears purple and the thickness of wall varies from 0.1 to 0.3 mm. The specimen is sectioned to reveal a smaller cyst measuring 1.1 cm in diameter to 2.2 cm in diameter. The tumor varies from white-tan homogeneous areas to areas of papillary excrescences. The ovarian remnant is not identified. The frozen section remnant is submitted in block A1, representative section of the fallopian tube is submitted in A2, and representative sections of the specimen are submitted in blocks A3-7.

B. "Right tube and ovary", received fresh and placed in formalin. The specimen consists of a pink-tan aggregate measuring 11 x 10 x 6 cm and weighing 231.5 gram, with an associated fallopian tube measuring 6 cm in length and 1.2 cm in diameter. The surface of the specimen varies from pink-tan and has areas of excrescences and granulations. There are also prominent areas of adhesions on the surface of this specimen. The specimen is serially sectioned to reveal an area measuring 4.5 x 4 x 3.5 cm containing pink-tan friable solid contents with a small volume of brown fluid. The solid contents reveal a central area of necrosis, with areas of papillary excrescences. The frozen section remnant corresponding to BF1 is submitted in B1. Representative sections of the fallopian tube are submitted in B2. Representative sections of solid and cystic contents of the specimen are submitted in B3-6.

C. "Uterus and cervix", received fresh and placed in formalin. A 90.4 gram, 9 x 8.2 x 3.7 cm fragment of pink-tan tissue is received. The surface of the specimen is pink-tan, glistening but has areas of granulation and adhesions. There is also a cystic structure attached to the surface which measures 3 x 2 x 2 cm. The cystic area, on section, reveals a brown colored fluid and no solid contents. The cervical os measures 0.3 cm and is slit like. The os is also stenotic and the specimen is difficult to open. On sectioning the cervix is 2.6 x 2 cm. Further sectioning reveals leiomyoma which measures 2 x 2 x 1.5 cm, and is intramural. Representative sections are submitted in blocks C1-6.

D. "Omentum", received in formalin. The specimen consists of yellow-tan lobulated fibroadipose tissue, measuring 40 x 12 x 0.8 cm, consistent with adipose tissue. There are several areas of gray-white nodularity varying from 0.5 to 1 cm in diameter. Representative sections are submitted in blocks D1-2.

BLOCK SUMMARY:

- A1- frozen section remnant corresponding to AF1
- A2- left fallopian tube
- A3-7- left ovarian specimen
- B1- frozen section remnant corresponding to BF1
- B2- right fallopian tube
- B3-6- right ovarian specimen

[page 2 of 3]
C1-6- representative sections of the uterus
D1-2- omentum

[REDACTED]

INTRA OPERATIVE CONSULTATION:

- A. "Left ovary and tube": AF1- carcinoma present
B. "Right tube and ovary": BF1- adenocarcinoma

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

PATHOLOGIC STAGE:

PROCEDURE: Hysterosalpingo-oophorectomy

PATHOLOGIC STAGE (AJCC 6th Edition): pT3a pNx pMx

NOTE: Information on pathology stage and the operative procedure is transmitted to this Institution's Cancer Registry as required for accreditation by the Commission on Cancer. Pathology stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

A. "LEFT OVARY AND TUBE":

TYPE: PAPILLARY SEROUS ADENOCARCINOMA
FIGO GRADE: 3
TUMOR SIZE: 10 X 6.5 X 4 CM.
WEIGHT: 98.9 GRAMS
SEROSA: POSITIVE FOR CARCINOMA

LEFT FALLOPIAN TUBE, NEGATIVE FOR MALIGNANCY.

B. "RIGHT TUBE AND OVARY":

TYPE: PAPILLARY SEROUS ADENOCARCINOMA
FIGO GRADE: 3
TUMOR SIZE: 11 X 10 X 6 CM.
WEIGHT: 231.5 GRAMS
SEROSA: POSITIVE FOR CARCINOMA

RIGHT FALLOPIAN TUBE, NEGATIVE FOR MALIGNANCY.

C. "UTERUS AND CERVIX":

UTERUS, 90.4 GRAMS
ENDOMETRIUM: ATROPHIC
MYOMETRIUM: AREA OF SEROUS ADENOCARCINOMA (3 X 2 CM)
CERVIX: FOCAL VASCULAR INVASION BY SEROUS ADENOCARCINOMA
SEROSA: POSITIVE FOR SEROUS PAPILLARY ADENOCARCINOMA.
MARGINS: MUCOSAL SURGICAL MARGINS NEGATIVE FOR MALIGNANCY.

ADDITIONAL FINDINGS: LEIOMYOMA.

D. "OMENTUM" (PARTIAL RESECTION):

ADIPOSE TISSUE WITH PAPILLARY SEROUS ADENOCARCINOMA.

COMMENT: The tumor cells, with immunoperoxidase stains, are positive for WT-1,

[REDACTED]

[page 3 of 3]
CK-7, and BerEp4, and are negative for CK20 and calretinin. This pattern of staining is consistent with papillary serous carcinoma of the ovary.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Performed by:

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 78496315-5b34-4f1a-bec1-fb74f5b596a7 (TCGA-29-1704.FC9D68CC-38CF-4321-94CC-F030FAEE7DB3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).